Somatic mutation profile of tumor specimen TCGA-D9-A6EA-06A (aliquot TCGA-D9-A6EA-06A-11D-A30X-08) from TCGA case TCGA-D9-A6EA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.2 years (26,004 days).
Specimen TCGA-D9-A6EA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af9306d3-4514-4945-b7ef-9bf6af1526d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A6EA-10A (Blood Derived Normal), aliquot TCGA-D9-A6EA-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/079b4036-b853-4b31-8a0b-ca4f2bea4d96

The open-access MAF lists 796 somatic variants for this specimen: 516 protein-altering or splice-affecting, 262 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 476, Silent 262, Nonsense Mutation 29, Intron 9, RNA 6, Splice Region 5, Frame Shift Del 3, Splice Site 3, 3'UTR 2, 3'Flank 1.

Variants (750 of 796; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HGF | c.495G>A p.S165= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs137853235, CS094308, COSV55948710; ClinVar: pathogenic; called by muse, mutect2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 197/217 reads (91%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 55/105 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.076); catalogued as COSV101329961, COSV70027848; called by muse, mutect2, varscan2
- ABCC8 | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 85/120 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56849796; called by muse, mutect2, varscan2
- ABHD16A | c.411C>A p.N137K | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV65451750; called by muse, mutect2, varscan2
- ABHD8 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.136); catalogued as COSV53112809; called by muse, mutect2, varscan2
- ACAN | c.2437C>T p.P813S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.118); catalogued as COSV61355052; called by muse, mutect2
- ACAN | c.5227C>T p.P1743S | Missense Mutation (SNP) | VAF 91/155 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61359808; called by muse, mutect2, varscan2
- ACOXL | c.1407G>A p.W469* (on ENST00000389811 / NM_001371254.1; = p.W439* on NM_001142807.4) | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as COSV67735642; called by muse, mutect2, varscan2
- ACSM1 | c.942T>A p.F314L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV54635332, COSV54635527; called by muse, mutect2, varscan2
- ACSM2B | c.1115T>A p.V372D | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.889); catalogued as COSV61657664; called by muse, mutect2, varscan2
- ACSM4 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs756182664, COSV68066508; called by muse, mutect2, varscan2
- ACSM4 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV101257096; called by muse, mutect2, varscan2
- ADAM11 | c.1629C>G p.Y543* | Nonsense Mutation (SNP) | VAF 118/146 reads (81%) | catalogued as COSV52345999; called by muse, mutect2, varscan2
- ADAMTS18 | c.3281G>A p.R1094Q | Missense Mutation (SNP) | VAF 163/299 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs373807615, COSV51407429; called by muse, mutect2, varscan2
- ADCY5 | c.3054G>A p.W1018* | Nonsense Mutation (SNP) | VAF 32/46 reads (70%) | catalogued as COSV59197309; called by muse, mutect2, varscan2
- ADCY7 | c.1452G>A p.M484I | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV54266390; called by muse, mutect2, varscan2
- ADGRB3 | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65393390; called by muse, mutect2, varscan2
- ADGRV1 | c.5266G>A p.E1756K | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.43); PolyPhen benign (0.034); catalogued as rs1027911338, COSV67980079; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADRA1A | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV52362905, COSV99370686; called by muse, mutect2, varscan2
- ADRA2B | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs761772454, COSV69787453; called by muse, mutect2, varscan2
- AFAP1L1 | c.1556C>G p.A519G | Missense Mutation (SNP) | VAF 92/108 reads (85%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV57044407, COSV57044996; called by muse, mutect2, varscan2
- AFF2 | c.3677G>A p.G1226E | Missense Mutation (SNP) | VAF 53/54 reads (98%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as COSV53987746; called by muse, mutect2, varscan2
- AHNAK2 | c.10711C>T p.L3571F | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs1226547015, COSV100317077; called by muse, mutect2, varscan2
- AKAP9 | c.9128T>C p.F3043S (on ENST00000359028; = p.F3019S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV62344723; called by muse, mutect2, varscan2
- ALK | c.1372C>T p.H458Y | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV66566606; called by muse, mutect2, varscan2
- ALOX12B | c.710A>T p.K237M | Missense Mutation (SNP) | VAF 107/118 reads (91%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV59872574; called by muse, mutect2, varscan2
- ALPK2 | c.4336G>A p.E1446K | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs539279339, COSV64492681; called by muse, mutect2, varscan2
- AMY1C | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 93/611 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771811270, COSV64406983; called by muse, mutect2, varscan2
- ANKIB1 | c.2932C>T p.H978Y | Missense Mutation (SNP) | VAF 107/187 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV56060984, COSV56061002; called by muse, mutect2, varscan2
- ANKRD49 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 49/63 reads (78%) | catalogued as rs374058506; called by muse, mutect2, varscan2
- ANKS4B | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61139134; called by muse, mutect2, varscan2
- ANLN | c.2768C>T p.S923L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV56075750; called by muse, mutect2, varscan2
- ANO2 | c.1420G>A p.E474K (on ENST00000356134 / NM_001278597.3; = p.E478K on NM_001278596.3) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV59021118; called by muse, mutect2, varscan2
- ANPEP | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55591223; called by muse, mutect2, varscan2
- AP1G1 | c.808A>T p.I270L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.077); catalogued as COSV55488769; called by muse, mutect2, varscan2
- AP3D1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61427677; called by muse, mutect2
- AP4E1 | c.3182C>T p.S1061F | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV55916756; called by muse, mutect2, varscan2
- APOH | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52772414, COSV99235788; called by muse, mutect2, varscan2
- AQP4 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV67218604; called by muse, mutect2, varscan2
- ARHGAP25 | c.745C>T p.P249S (on ENST00000409202 / NM_001007231.3; = p.P241S on NM_014882.3) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54901898; called by muse, mutect2, varscan2
- ARHGAP39 | c.2815G>A p.E939K (on ENST00000276826 / NM_001308208.2; = p.E970K on NM_025251.2) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1277135072, COSV52769573; called by muse, mutect2, varscan2
- ARMC3 | c.2145G>A p.W715* | Nonsense Mutation (SNP) | VAF 32/38 reads (84%) | catalogued as rs756978143, COSV53060651; called by muse, mutect2, varscan2
- ASB5 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.112); catalogued as COSV56668570; called by muse, mutect2, varscan2
- ASIC4 | c.434A>T p.K145I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.737); catalogued as COSV61731691; called by muse, mutect2, varscan2
- ASXL1 | c.3218G>T p.R1073L | Missense Mutation (SNP) | VAF 109/209 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV60104419, COSV60107297; called by muse, mutect2, varscan2
- ASXL3 | c.2150C>T p.S717L | Missense Mutation (SNP) | VAF 198/287 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52464665; called by muse, mutect2, varscan2
- ATF4 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV57478786; called by muse, mutect2, varscan2
- ATG16L2 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.677); catalogued as rs749372930, COSV58361622; called by muse, mutect2, varscan2
- ATM | c.8948C>G p.T2983S | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as COSV53741408; called by muse, mutect2
- ATP12A | c.2197G>A p.G733R | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566077545, COSV54515540; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV57748949; called by muse, mutect2, varscan2
- ATP8B1 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52175292; called by muse, mutect2, varscan2
- ATP9B | c.2425C>T p.R809* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as rs147932692; called by muse, mutect2, varscan2
- ATR | c.3898C>T p.R1300C | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779170933, COSV63386190; called by muse, mutect2, varscan2
- ATXN2L | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV57369554; called by muse, mutect2, varscan2
- AVIL | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV57681672; called by muse, mutect2, varscan2
- BCL11A | c.2020G>A p.G674R (on ENST00000335712 / NM_001365609.1; = p.G708R on NM_018014.4) | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59629118, COSV59637864; called by muse, mutect2, varscan2
- BCL2L14 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs774795644, COSV53786830; called by muse, mutect2, varscan2
- BMP5 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63701639, COSV63701737; called by muse, mutect2, varscan2
- BPIFB1 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as rs952016082, COSV53606432; called by muse, mutect2, varscan2
- BTNL8 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV51458390; called by muse, mutect2, varscan2
- C6 | c.1028A>T p.N343I | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV54709558; called by muse, mutect2, varscan2
- CABP1 | c.1072C>T p.R358* (on ENST00000316803 / NM_001033677.1; = p.R155* on NM_004276.5) | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as rs1197561621, COSV99974660; called by muse, mutect2, varscan2
- CABP4 | c.801G>A p.E267= | Splice Region (SNP) | VAF 35/57 reads (61%) | catalogued as rs1226636100, COSV100351497; called by muse, mutect2, varscan2
- CABP4 | c.802T>G p.F268V | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100351498; called by muse, mutect2, varscan2
- CACNA1C | c.5938G>A p.D1980N (on ENST00000399634 / NM_001167625.1; = p.D1909N on NM_000719.7) | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV59713980; called by muse, mutect2, varscan2
- CACNA2D3 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV55535275; called by muse, mutect2, varscan2
- CATSPERB | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56423599; called by muse, mutect2, varscan2
- CAV3 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV57479130; called by muse, mutect2
- CCDC141 | c.2042A>T p.K681I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV55372890; called by muse, mutect2, varscan2
- CCDC157 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV100600246; called by muse, mutect2
- CCDC73 | c.350A>C p.K117T | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58797993; called by muse, mutect2
- CCDC91 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60340483; called by muse, mutect2, varscan2
- CDCA2 | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1309677444, COSV57945455, COSV57945711; called by muse, mutect2, varscan2
- CDH12 | c.2068C>T p.R690C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66402345; called by muse, mutect2, varscan2
- CDIN1 | c.301C>T p.R101W (on ENST00000437989; = p.R3W on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs201835784; called by muse, mutect2, varscan2
- CELSR3 | c.5021G>A p.G1674E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50854901; called by muse, mutect2, varscan2
- CFAP100 | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1203410755, COSV61502964; called by muse, mutect2, varscan2
- CFAP47 | c.1352A>T p.K451I | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV52883983; called by muse, mutect2, varscan2
- CFAP94 | c.707G>A p.G236E (on ENST00000320267 / NM_001352064.2; = p.G242E on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57231932; called by muse, mutect2, varscan2
- CHRD | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52607468; called by muse, mutect2, varscan2
- CHRM2 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.719); catalogued as COSV57771117; called by muse, mutect2, varscan2
- CHST1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs769838351, COSV57323412; called by muse, mutect2, varscan2
- CHST5 | c.426T>A p.F142L | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60338916; called by muse, mutect2, varscan2
- CIT | c.4465C>T p.P1489S | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs1022382362, COSV55867466; called by muse, mutect2, varscan2
- CLSTN3 | c.2623C>T p.R875C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs201799321; called by muse, mutect2
- CNOT10 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as COSV59391832; called by muse, mutect2, varscan2
- CNR1 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV62987085; called by muse, mutect2, varscan2
- CNTN1 | c.2914T>A p.Y972N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV61639277; called by muse, mutect2, varscan2
- CNTNAP5 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.902); catalogued as COSV101443908, COSV70473101, COSV70484268; called by muse, mutect2, varscan2
- COL11A1 | c.3740C>T p.S1247L | Missense Mutation (SNP) | VAF 186/195 reads (95%) | SIFT tolerated (0.15); PolyPhen benign (0.15); catalogued as COSV62178157; called by muse, mutect2, varscan2
- COL17A1 | c.2729C>T p.P910L | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1434168769, COSV62226552; called by muse, mutect2, varscan2
- COL20A1 | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as COSV100490407; called by muse, mutect2, varscan2
- COL20A1 | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); catalogued as rs779538334, COSV100490408; called by muse, mutect2, varscan2
- COL2A1 | c.4085G>A p.G1362E | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV61530159, COSV61532321; called by muse, mutect2, varscan2
- COL2A1 | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61530170; called by muse, mutect2, varscan2
- COL4A3 | c.2525G>A p.G842E | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67415256; called by muse, mutect2, varscan2
- COL4A4 | c.2065G>A p.G689R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1419631048, COSV61631775, COSV61635200; called by muse, mutect2, varscan2
- COL4A6 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.466); catalogued as COSV57865318; called by muse, mutect2, varscan2
- COL5A3 | c.4763C>T p.P1588L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53406980; called by muse, mutect2, varscan2
- COL6A6 | c.6022G>A p.D2008N | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62024004; called by muse, mutect2, varscan2
- COL7A1 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV60392858; called by muse, mutect2, varscan2
- CPA3 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56044943; called by muse, mutect2, varscan2
- CPEB1 | c.1434T>A p.F478L (on ENST00000617958; = p.F413L on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV55618754; called by muse, mutect2, varscan2
- CPLX4 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV104409774, COSV55313570, COSV55313932; called by muse, mutect2
- CRISP2 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs141421430; called by muse, mutect2, varscan2
- CRYBB1 | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV53233123; called by muse, mutect2, varscan2
- CSMD1 | c.4055C>G p.S1352C (on ENST00000520002; = p.S1351C on NM_033225.6) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs940985358, COSV59317448; called by muse, mutect2, varscan2
- CYP11B1 | c.548G>A p.S183N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1296590244, COSV52825805; called by muse, mutect2, varscan2
- CYP2B6 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV57843534; called by muse, mutect2, varscan2
- CYTIP | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as rs371815413, COSV51633532; called by muse, mutect2, varscan2
- DBH | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748099306; called by muse, mutect2, varscan2
- DCAF8L1 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as COSV71595254, COSV71595276; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 85/153 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by muse, mutect2, varscan2
- DGKB | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.827); catalogued as COSV51779744; called by muse, mutect2, varscan2
- DHH | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as COSV57201908; called by muse, mutect2, varscan2
- DHRS2 | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs770547730, COSV51631722; called by muse, mutect2, varscan2
- DLC1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.146); catalogued as COSV52301736; called by muse, mutect2, varscan2
- DNAH10 | c.10324G>A p.D3442N (on ENST00000409039; = p.D3381N on NM_207437.3) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV68992785; called by muse, mutect2
- DNAH17 | c.10219G>A p.D3407N | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV67753544; called by muse, mutect2, varscan2
- DNAH3 | c.4402T>C p.F1468L | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV54519216; called by muse, mutect2, varscan2
- DNAH5 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV54221745; called by muse, mutect2, varscan2
- DNAH8 | c.6710C>T p.P2237L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1278517785, COSV59442668; called by muse, mutect2, varscan2
- DNAI1 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54280671; called by muse, mutect2, varscan2
- DPH1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 65/76 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775796897, COSV53984499; called by muse, mutect2, varscan2
- DRAM1 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.167); catalogued as COSV51597525, COSV99315840; called by muse, mutect2, varscan2
- DSG1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs754465552, COSV57135031; called by muse, mutect2, varscan2
- EFCAB13 | c.1081A>G p.K361E | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs1179169450, COSV58945821, COSV58948050; called by muse, mutect2, varscan2
- EGFLAM | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.174); catalogued as rs1401024420, COSV59299398; called by muse, mutect2, varscan2
- EIF2AK3 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as rs757246219, CM097416, COSV57547110; called by muse, mutect2, varscan2
- ELAC1 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as rs778285548, COSV53996494; called by muse, mutect2, varscan2
- ELAVL4 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 122/128 reads (95%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV63915677; called by muse, mutect2, varscan2
- ELK1 | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55952794; called by muse, mutect2, varscan2
- ELP1 | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65897446; called by muse, mutect2, varscan2
- EME1 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 55/62 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV56812416; called by muse, mutect2, varscan2
- EPHA4 | c.2758C>T p.L920F | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56031891; called by muse, mutect2, varscan2
- ERBB4 | c.3187C>T p.Q1063* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as rs1254318693, COSV61483996, COSV61491924; called by muse, mutect2
- ERC2 | c.2291A>C p.K764T | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV55619084; called by muse, mutect2, varscan2
- ERCC4 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61311850; called by muse, mutect2, varscan2
- ERN1 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV70500344; called by muse, mutect2, varscan2
- F3 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 78/82 reads (95%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as COSV61844964; called by muse, mutect2, varscan2
- FAM120C | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV60259104; called by muse, mutect2, varscan2
- FAM135B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as rs746767621, COSV50525623; called by muse, mutect2, varscan2
- FAM234B | c.602T>A p.L201H | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV52194422; called by muse, mutect2, varscan2
- FAM237A | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV69305051; called by muse, mutect2
- FAT4 | c.13051C>T p.P4351S | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs1406382876, COSV58682621; called by muse, mutect2, varscan2
- FBN1 | c.3676G>A p.G1226R | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM118912, COSV57315537; called by muse, mutect2, varscan2
- FCGBP | c.2194G>A p.V732I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.02); catalogued as rs1449613085; called by muse, mutect2, varscan2
- FGF23 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV52975948; called by muse, varscan2
- FHDC1 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as rs1301059890, COSV52599507; called by muse, mutect2, varscan2
- FHOD1 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0.127); catalogued as COSV99264041; called by muse, mutect2, varscan2
- FILIP1 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV52722183; called by muse, mutect2, varscan2
- FLAD1 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 165/177 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52696877; called by muse, mutect2, varscan2
- FLG | c.10412G>T p.G3471V | Missense Mutation (SNP) | VAF 673/726 reads (93%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100911793, COSV64241254; called by muse, mutect2, varscan2
- FLG | c.5296C>T p.L1766F | Missense Mutation (SNP) | VAF 422/452 reads (93%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.979); catalogued as rs1200210234, COSV64241264; called by muse, varscan2
- FMN2 | c.3229C>T p.P1077S | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV100144632; called by muse, varscan2
- FNDC1 | c.3935C>T p.S1312F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV51936789; called by muse, mutect2, varscan2
- FOXI1 | c.766T>A p.S256T | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV60388511; called by muse, mutect2, varscan2
- FOXJ1 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.905); catalogued as rs1266769878, COSV53943856; called by muse, mutect2, varscan2
- FSD1 | c.404A>G p.K135R | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as COSV55695925; called by muse, mutect2, varscan2
- FSHB | c.79A>T p.T27S | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.618); catalogued as COSV54221699; called by muse, mutect2, varscan2
- FST | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV56815563; called by muse, mutect2, varscan2
- FSTL4 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 16/21 reads (76%) | catalogued as rs148048628; called by muse, mutect2, varscan2
- FURIN | c.452T>A p.I151N | Missense Mutation (SNP) | VAF 105/175 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51576506; called by muse, mutect2, varscan2
- GAS2L3 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57156398; called by muse, mutect2, varscan2
- GCK | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 195/357 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as CM096804, COSV61753517; called by muse, mutect2, varscan2
- GDAP1L1 | c.214T>G p.C72G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1448837597, COSV61156771; called by muse, mutect2, varscan2
- GIMAP4 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs1352695671, COSV55432152; called by muse, mutect2, varscan2
- GLCE | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.265); catalogued as COSV55945622; called by muse, mutect2, varscan2
- GLRB | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.807); catalogued as COSV100030071, COSV52416446; called by muse, mutect2, varscan2
- GPC5 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 118/158 reads (75%) | SIFT tolerated (0.58); PolyPhen benign (0.042); catalogued as COSV65595708; called by muse, mutect2, varscan2
- GPR143 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV66632365; called by muse, mutect2, varscan2
- GPR55 | c.739T>C p.F247L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV67407636; called by muse, mutect2, varscan2
- GPR65 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50862625; called by muse, mutect2, varscan2
- GPRASP2 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 89/101 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs762327307, COSV59990813; called by muse, mutect2, varscan2
- GREB1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV52186070; called by muse, mutect2, varscan2
- GRIA2 | c.1572G>A p.M524I | Missense Mutation (SNP) | VAF 146/217 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52381882, COSV52385249; called by muse, mutect2, varscan2
- GRID2 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749223378, COSV56185857, COSV99944022; called by muse, mutect2, varscan2
- GRM3 | c.2568C>T p.S856= | Splice Region (SNP) | VAF 37/74 reads (50%) | catalogued as rs753862702, COSV64471189; called by muse, mutect2, varscan2
- GSDMC | c.811A>G p.N271D | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV52695159; called by muse, mutect2, varscan2
- GSDMC | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52695171; called by muse, mutect2, varscan2
- GTF3C3 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV55831975; called by muse, mutect2, varscan2
- HCK | c.640A>C p.S214R | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.405); catalogued as COSV52942262; called by muse, mutect2, varscan2
- HECW1 | c.2768C>T p.A923V | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as COSV67828443, COSV67837632; called by muse, mutect2, varscan2
- HEPH | c.262G>A p.D88N (on ENST00000343002; = p.D142N on NM_138737.5) | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV57963054; called by muse, mutect2, varscan2
- HGF | c.497G>A p.S166N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.418); catalogued as rs373660832, COSV55951277; called by muse, mutect2
- HIP1 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV100417394; called by muse, mutect2, varscan2
- HMCN1 | c.15281C>T p.S5094F | Missense Mutation (SNP) | VAF 42/45 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV54897347; called by muse, mutect2, varscan2
- HOXA4 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.036); catalogued as rs1562721868, COSV57826165; called by muse, mutect2, varscan2
- HRH4 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 86/120 reads (72%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV56927964; called by muse, mutect2, varscan2
- HSPG2 | c.8602C>T p.P2868S | Missense Mutation (SNP) | VAF 90/102 reads (88%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV65971184; called by muse, mutect2, varscan2
- HTR5A | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs753684277, COSV55282760, COSV55286022; called by muse, mutect2, varscan2
- HUWE1 | c.12226C>T p.P4076S | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV53343955; called by muse, mutect2, varscan2
- IFNA14 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 153/178 reads (86%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs770723376, COSV66516099; called by muse, mutect2, varscan2
- IGF2BP3 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51683848; called by muse, mutect2, varscan2
- IGHG4 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 88/294 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.12); catalogued as rs587772292; called by muse, mutect2, varscan2
- IMMP2L | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (0.79); PolyPhen benign (0.021); catalogued as COSV59235890; called by muse, mutect2, varscan2
- IMPG1 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV64054658; called by muse, mutect2, varscan2
- INSRR | c.2188G>A p.V730M | Missense Mutation (SNP) | VAF 56/59 reads (95%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs777770717, COSV63871746; called by muse, mutect2, varscan2
- IQGAP2 | c.4721G>A p.G1574E | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV57172662; called by muse, mutect2, varscan2
- IRAK3 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV54161384; called by muse, mutect2, varscan2
- ITSN1 | c.2713C>T p.P905S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.474); catalogued as COSV66082802; called by muse, mutect2, varscan2
- JADE1 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56905753; called by muse, mutect2, varscan2
- KCNJ6 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV55713589; called by muse, mutect2, varscan2
- KCNK1 | c.520T>C p.F174L | Missense Mutation (SNP) | VAF 84/95 reads (88%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV64035031; called by muse, mutect2, varscan2
- KCNQ5 | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); catalogued as rs1562230186, COSV59658525; called by muse, mutect2, varscan2
- KCTD3 | c.911A>C p.N304T | Missense Mutation (SNP) | VAF 95/104 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52066337; called by muse, mutect2, varscan2
- KCTD3 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 112/117 reads (96%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.265); catalogued as rs1282734099, COSV52066344; called by muse, mutect2, varscan2
- KIDINS220 | c.5038C>T p.P1680S | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.293); catalogued as COSV56752907; called by muse, mutect2, varscan2
- KIF15 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100392769; called by muse, mutect2, varscan2
- KIR3DL1 | c.823A>C p.T275P | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100428526; called by muse, mutect2, varscan2
- KITLG | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as COSV57201239; called by muse, mutect2
- KITLG | c.195A>G p.P65= | Splice Region (SNP) | VAF 8/28 reads (29%) | catalogued as COSV57201247; called by muse, mutect2
- KLF10 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV53434866, COSV53435414; called by muse, mutect2, varscan2
- KLHDC10 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 81/138 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59051521; called by muse, mutect2, varscan2
- KLK8 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1223589391, COSV51591724; called by muse, mutect2, varscan2
- KRBA1 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1205537832, COSV55441257; called by muse, mutect2
- KRTAP10-1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV59955399; called by muse, mutect2, varscan2
- KRTAP13-4 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.829); catalogued as rs76547537, COSV61879152; called by muse, mutect2, varscan2
- LAD1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV66212406; called by muse, mutect2, varscan2
- LAMA5 | c.1738C>T p.H580Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV53358914; called by muse, mutect2, varscan2
- LAMB1 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs762419153, COSV55962917; called by muse, mutect2, varscan2
- LGI1 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1318179573, COSV65057418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LHCGR | c.1895G>A p.R632K | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.965); catalogued as COSV54296522, COSV54301274; called by muse, mutect2, varscan2
- LLGL2 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51350598, COSV51367929; called by muse, mutect2, varscan2
- LMBRD2 | c.42T>G p.F14L | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV56949725; called by muse, mutect2, varscan2
- LRG1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs375872172; called by muse, mutect2, varscan2
- LRP1B | c.7802G>A p.G2601E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101250987, COSV67213525; called by muse, mutect2, varscan2
- LRP1B | c.7327C>T p.R2443C | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774430605, COSV67190954; called by muse, mutect2, varscan2
- LRP1B | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67213531; called by muse, mutect2, varscan2
- LRRC3 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52399223; called by muse, mutect2, varscan2
- LRRC4C | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53424272; called by muse, mutect2, varscan2
- LRRIQ3 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs751081820, COSV63043342; called by muse, mutect2, varscan2
- LTBP2 | c.4396G>A p.G1466R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760036288, COSV56207632; called by muse, mutect2, varscan2
- LXN | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51832458; called by muse, mutect2
- LXN | c.194A>G p.Q65R | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV51832463; called by muse, mutect2
- MAGEC3 | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV53579597; called by muse, mutect2, varscan2
- MAGEE2 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.83); catalogued as COSV64897633; called by muse, mutect2, varscan2
- MAML1 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV52984971; called by muse, mutect2, varscan2
- MAP1A | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55808251; called by muse, mutect2, varscan2
- MAP2 | c.4649C>T p.P1550L | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as rs1360222952, COSV52289577; called by muse, mutect2, varscan2
- MAPK13 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV52982969; called by muse, mutect2, varscan2
- MARCO | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59054036; called by muse, mutect2, varscan2
- MATK | c.395C>T p.A132V (on ENST00000310132 / NM_139355.3; = p.A133V on NM_002378.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749206442, COSV59554390; called by muse, mutect2, varscan2
- MBD5 | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV68696838, COSV68698617; called by muse, mutect2, varscan2
- MCC | c.473T>G p.L158R | Missense Mutation (SNP) | VAF 296/343 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56728183; called by muse, mutect2, varscan2
- MDGA2 | c.2266G>A p.E756K (on ENST00000399232 / NM_001113498.2; = p.E458K on NM_182830.4) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.767); catalogued as COSV62090326, COSV62107352; called by muse, mutect2, varscan2
- MEIS2 | c.391C>T p.R131C (on ENST00000561208 / NM_170675.5; = p.R118C on NM_002399.3) | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54935092; called by muse, mutect2, varscan2
- MGAM | c.1409G>A p.R470K | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV72074548; called by muse, mutect2, varscan2
- MROH2B | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV68183526; called by muse, mutect2, varscan2
- MTERF3 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs148129681, COSV54632271; called by muse, mutect2, varscan2
- MTR | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 109/113 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63967180; called by muse, mutect2, varscan2
- MUC16 | c.22897G>A p.E7633K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.118); catalogued as COSV67462851; called by muse, mutect2, varscan2
- MUC16 | c.20227C>T p.L6743F | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.683); catalogued as COSV67462858; called by muse, mutect2, varscan2
- MUC16 | c.6578C>T p.S2193F | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67462513; called by muse, mutect2, varscan2
- MUC16 | c.3515C>T p.S1172L | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.112); catalogued as COSV67462867; called by muse, mutect2, varscan2
- MUC16 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.186); catalogued as COSV67462872; called by muse, mutect2, varscan2
- MUC17 | c.6364C>T p.L2122F | Missense Mutation (SNP) | VAF 179/386 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1485565948, COSV60287379; called by muse, mutect2, varscan2
- MUC5B | c.12248G>A p.G4083E | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as COSV71591775; called by muse, varscan2
- MYH1 | c.5515G>A p.E1839K | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56847549; called by muse, mutect2, varscan2
- MYH2 | c.4618G>A p.E1540K | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV55437198; called by muse, mutect2, varscan2
- MYH7 | c.3332T>G p.L1111R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV62518800; called by muse, mutect2, varscan2
- MYO15A | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 37/41 reads (90%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1450338630, COSV52755989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO5B | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1374951575, COSV53217796; called by muse, mutect2, varscan2
- MYRIP | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs772207839, COSV56868067; called by muse, mutect2, varscan2
- MYT1 | c.1289A>G p.K430R | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.37); catalogued as COSV60505157; called by muse, mutect2, varscan2
- NAA11 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV54514464; called by muse, mutect2, varscan2
- NALCN | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV51932915; called by muse, mutect2, varscan2
- NBAS | c.2012T>A p.F671Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55720155; called by muse, mutect2, varscan2
- NCAN | c.2952G>A p.W984* | Nonsense Mutation (SNP) | VAF 45/115 reads (39%) | catalogued as COSV53050481; called by muse, mutect2, varscan2
- NDRG4 | c.77C>T p.P26L (on ENST00000570248 / NM_001378344.1; = p.P58L on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99262005; called by muse, mutect2, varscan2
- NEDD1 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57143090; called by muse, varscan2
- NEDD1 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs749180864, COSV57143106; called by muse, varscan2
- NIPAL1 | c.391A>C p.N131H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55006459; called by muse, mutect2, varscan2
- NLRP4 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as rs775533945, COSV100017297, COSV56712882; called by muse, mutect2, varscan2
- NLRP7 | c.2326G>A p.E776K (on ENST00000340844 / NM_206828.3; = p.E748K on NM_139176.3) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1340954076, COSV60173901; called by muse, mutect2, varscan2
- NOL6 | c.2684C>T p.S895F | Missense Mutation (SNP) | VAF 50/52 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1413205765, COSV53041243; called by muse, mutect2, varscan2
- NOMO1 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 95/420 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99814438; called by muse, mutect2, varscan2
- NOMO1 | c.1454C>A p.P485H | Missense Mutation (SNP) | VAF 97/425 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.258); catalogued as COSV99814439; called by muse, mutect2, varscan2
- NONO | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV52137317, COSV52141002; called by muse, mutect2, varscan2
- NPFFR2 | c.1188G>A p.M396I | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV58146391, COSV58149220; called by muse, mutect2, varscan2
- NPHS1 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as rs760440966, COSV62286459; called by muse, mutect2, varscan2
- NPL | c.345C>A p.F115L | Missense Mutation (SNP) | VAF 59/64 reads (92%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV51123412; called by muse, mutect2, varscan2
- NRCAM | c.497C>T p.P166L (on ENST00000379028 / NM_001371124.1; = p.P160L on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs1320066352, COSV61035739; called by muse, mutect2, varscan2
- NRG3 | c.1822G>A p.E608K (on ENST00000404547 / NM_001370084.1; = p.E584K on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.6); catalogued as rs1343504425, COSV64559252, COSV64569676; called by muse, mutect2, varscan2
- NT5DC2 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58735572; called by muse, mutect2
- OAZ3 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 46/47 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1409967510, COSV58618123; called by muse, mutect2, varscan2
- OPRL1 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV61091619; called by muse, mutect2, varscan2
- OR10A5 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 72/112 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV55054018; called by muse, mutect2, varscan2
- OR1M1 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as COSV70036839; called by muse, mutect2, varscan2
- OR2A25 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 126/374 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV68717133; called by muse, mutect2, varscan2
- OR2S2 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV59529934; called by muse, mutect2, varscan2
- OR4C46 | c.233A>C p.N78T | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV60219182, COSV60221186; called by muse, mutect2, varscan2
- OR4F6 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV61026708; called by muse, mutect2, varscan2
- OR51B6 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 47/69 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV66512358; called by muse, mutect2, varscan2
- OR52M1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs61751908, COSV64173096; called by muse, mutect2, varscan2
- OR5AS1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57981336; called by muse, mutect2, varscan2
- OR6C3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); catalogued as rs866375503, COSV65570631; called by muse, mutect2, varscan2
- OR7C2 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50180525; called by muse, mutect2, varscan2
- OR7E24 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV101509639, COSV71702199; called by muse, mutect2, varscan2
- OR9I1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as rs1487173238, COSV56925402; called by muse, mutect2, varscan2
- OTOF | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as COSV55502517; called by muse, mutect2
- OXGR1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53657151, COSV53657698; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.704C>T p.P235L (on ENST00000259318 / NM_001136562.3; = p.P466L on NM_007203.5) | Missense Mutation (SNP) | VAF 49/54 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52175765; called by muse, mutect2, varscan2
- PAPPA | c.4348G>A p.G1450R | Missense Mutation (SNP) | VAF 60/68 reads (88%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.931); catalogued as COSV60282382; called by muse, mutect2, varscan2
- PARD3B | c.3446C>T p.P1149L (on ENST00000406610 / NM_001302769.2; = p.P1080L on NM_057177.7) | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV62510150; called by muse, mutect2, varscan2
- PARP15 | c.1531G>A p.D511N (on ENST00000464300 / NM_001113523.3; = p.D277N on NM_152615.2) | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV59972433; called by muse, mutect2, varscan2
- PAX9 | c.257A>C p.H86P | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64061508; called by muse, mutect2, varscan2
- PBRM1 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV56273860; called by muse, mutect2, varscan2
- PCBP3 | c.281C>A p.T94K | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68407801; called by muse, mutect2, varscan2
- PCDH11X | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV53450226; called by muse, mutect2, varscan2
- PCDHA10 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 89/657 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56497384; called by muse, mutect2, varscan2
- PCDHA8 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 39/269 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.029); catalogued as COSV65336573; called by muse, mutect2, varscan2
- PCDHGA2 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 158/196 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53938726; called by muse, mutect2, varscan2
- PDXDC1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV57906403; called by muse, mutect2
- PHLDB2 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV67310815; called by muse, mutect2, varscan2
- PIK3AP1 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59532046; called by muse, mutect2, varscan2
- PKHD1 | c.2477C>T p.S826F | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV61861160, COSV61877237; called by muse, mutect2, varscan2
- PKHD1L1 | c.9216G>A p.M3072I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV65742180; called by muse, mutect2
- PKHD1L1 | c.10372G>A p.G3458R | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV65742186; called by muse, mutect2, varscan2
- PLA2G2D | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs370789632, COSV100908027; called by muse, mutect2, varscan2
- PLB1 | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as COSV59824188; called by muse, mutect2, varscan2
- PLCB4 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV53799943, COSV53800298; called by muse, mutect2, varscan2
- PLCB4 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1418844892, COSV53794026; called by muse, mutect2, varscan2
- PLCH1 | c.4898C>T p.S1633F (on ENST00000340059 / NM_001130960.2; = p.S1625F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100398088, COSV58195696; called by muse, mutect2, varscan2
- PLCH1 | c.3676C>T p.H1226Y (on ENST00000340059 / NM_001130960.2; = p.H1218Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.04); catalogued as COSV58195715; called by muse, mutect2, varscan2
- PLG | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV51982598; called by muse, mutect2, varscan2
- PLIN4 | c.2690G>A p.G897E (on ENST00000301286; = p.G912E on NM_001367868.2) | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as COSV56690706; called by muse, mutect2, varscan2
- PLIN5 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV67850653; called by muse, mutect2, varscan2
- PLK2 | c.1847T>A p.F616Y | Missense Mutation (SNP) | VAF 216/321 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57107062; called by muse, mutect2, varscan2
- PLXND1 | c.4663C>T p.P1555S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60712835; called by muse, mutect2, varscan2
- PODN | c.1496G>A p.R499Q (on ENST00000395871; = p.R451Q on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/43 reads (95%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs372626429; called by muse, mutect2, varscan2
- POF1B | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as rs1569282856, COSV53133633; called by muse, mutect2, varscan2
- POLD1 | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101486827; called by muse, mutect2, varscan2
- POLI | c.1279C>T p.H427Y | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54188465; called by muse, mutect2, varscan2
- POM121L12 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs777301332, COSV68692860; called by muse, mutect2, varscan2
- PON1 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs1226777136, COSV55931668; called by muse, mutect2, varscan2
- POP1 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.208); catalogued as COSV62892606; called by muse, mutect2, varscan2
- POU2AF1 | c.90A>T p.E30D | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs533458963, COSV67577204; called by muse, mutect2, varscan2
- POU2F3 | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 115/170 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52793624; called by muse, mutect2, varscan2
- POU3F3 | c.1171A>T p.T391S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.057); catalogued as COSV100796853; called by muse, varscan2
- POU3F3 | c.1172C>T p.T391I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100796854; called by muse, varscan2
- PPEF2 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.329); catalogued as COSV54422084; called by muse, mutect2, varscan2
- PPIL2 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV58606267; called by muse, mutect2, varscan2
- PPP1R14C | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV63173962; called by muse, mutect2
- PPP2R2A | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV60096760; called by muse, mutect2, varscan2
- PPP2R3B | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV66813218; called by muse, mutect2, varscan2
- PPP6R3 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55725738; called by muse, mutect2, varscan2
- PRDM16 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 88/103 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762494143, COSV99576308; called by muse, mutect2, varscan2
- PROM2 | c.464T>C p.M155T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.355); catalogued as COSV58297877; called by muse, mutect2, varscan2
- PRR14 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV54911659; called by muse, mutect2, varscan2
- PRSS53 | c.220A>C p.T74P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54924035; called by muse, mutect2, varscan2
- PSMD4 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 146/151 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV64393360; called by muse, mutect2, varscan2
- PTPRB | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.893); catalogued as COSV54239606; called by muse, mutect2, varscan2
- PTPRN2 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 133/384 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV67035591; called by muse, mutect2
- RAB27B | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100024074; called by muse, mutect2
- RASAL2 | c.2654C>T p.P885L | Missense Mutation (SNP) | VAF 93/96 reads (97%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.546); catalogued as COSV62712388; called by muse, mutect2, varscan2
- RBP3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 54/66 reads (82%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1435092552; called by muse, mutect2, varscan2
- RBPJ | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV60750812; called by mutect2, varscan2
- RDX | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58193213; called by muse, mutect2, varscan2
- RELN | c.7034C>T p.P2345L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs760503401, COSV58999744; called by muse, mutect2, varscan2
- RHOH | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.062); catalogued as COSV67805521; called by muse, mutect2, varscan2
- RIPOR2 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.82); PolyPhen benign (0.108); catalogued as rs368504986, COSV52416925; called by muse, mutect2, varscan2
- RNASE13 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 86/148 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV58794509; called by muse, mutect2, varscan2
- ROBO4 | c.2057G>A p.G686E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV60623651; called by muse, mutect2, varscan2
- RP1L1 | c.5726C>T p.P1909L | Missense Mutation (SNP) | VAF 196/383 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs866793731, COSV66754536; called by muse, mutect2, varscan2
- RPH3A | c.518A>C p.K173T (on ENST00000389385 / NM_001143854.2; = p.K169T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101231810; called by muse, mutect2, varscan2
- RRP1B | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV61478998; called by muse, mutect2, varscan2
- RRP36 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | catalogued as COSV55064140; called by muse, mutect2, varscan2
- RUNX1T1 | c.993G>A p.G331= (on ENST00000265814 / NM_001198628.1; = p.G304= on NM_004349.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 54/187 reads (29%) | catalogued as rs751118196, COSV56142861, COSV56164150; called by muse, mutect2, varscan2
- RXRG | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 69/75 reads (92%) | SIFT tolerated, low confidence (0.61); PolyPhen probably damaging (0.994); catalogued as rs370579158; called by muse, mutect2, varscan2
- SACS | c.4447C>T p.Q1483* | Nonsense Mutation (SNP) | VAF 34/37 reads (92%) | catalogued as COSV66539145; called by muse, mutect2, varscan2
- SAG | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1383103616, COSV68590940; called by muse, mutect2, varscan2
- SCN10A | c.2630G>A p.G877E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV71861189; called by muse, mutect2, varscan2
- SCN5A | c.5960A>T p.N1987I (on ENST00000333535 / NM_198056.3; = p.N1986I on NM_000335.5) | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as COSV61122815; called by muse, mutect2, varscan2
- SCN7A | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.251); catalogued as rs1448558691, COSV69271113; called by muse, mutect2, varscan2
- SCUBE1 | c.2359T>A p.S787T | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as COSV62612118; called by muse, mutect2, varscan2
- SCYL1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV54212353; called by muse, mutect2, varscan2
- SDK2 | c.3356C>T p.P1119L | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66185377; called by muse, mutect2, varscan2
- SEMA3B | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs781984445; called by muse, mutect2
- SEMA5A | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as rs1561095332, COSV66791686; called by muse, mutect2, varscan2
- SERPINA7 | c.554T>A p.V185D | Missense Mutation (SNP) | VAF 71/84 reads (85%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59665670; called by muse, mutect2, varscan2
- SESN1 | c.1330C>T p.P444S (on ENST00000356644 / NM_001199933.1; = p.P503S on NM_014454.3) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57420727; called by muse, mutect2, varscan2
- SESTD1 | c.1951T>A p.Y651N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.276); catalogued as COSV58931088; called by muse, mutect2, varscan2
- SFTPB | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV60893175; called by muse, mutect2, varscan2
- SGSM1 | c.3046G>A p.G1016R (on ENST00000400359 / NM_001039948.4; = p.G955R on NM_133454.3) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167860576, COSV68508979; called by muse, mutect2, varscan2
- SH3RF3 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58685389; called by muse, mutect2, varscan2
- SH3TC1 | c.2801C>T p.S934L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs986368503, COSV55283847, COSV99795124; called by muse, mutect2, varscan2
- SHANK2 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1555153976, COSV53593387; called by muse, mutect2, varscan2
- SIM1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as rs201038781, CM136554, COSV53491648; called by muse, mutect2, varscan2
- SKA1 | c.679A>T p.K227* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV53278800; called by muse, mutect2, varscan2
- SLC12A1 | c.3057G>A p.W1019* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | catalogued as COSV66794389; called by muse, mutect2, varscan2
- SLC22A9 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54166048; called by muse, mutect2, varscan2
- SLC25A2 | c.259T>C p.F87L | Missense Mutation (SNP) | VAF 203/252 reads (81%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV53403641; called by muse, mutect2, varscan2
- SLC2A10 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV63714420; called by muse, mutect2, varscan2
- SLC35G3 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 85/100 reads (85%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52011052; called by muse, mutect2, varscan2
- SLC3A1 | c.483G>A p.W161* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV53222413; called by muse, mutect2, varscan2
- SLC49A3 | c.996+1G>A p.X332_splice (on ENST00000404286 / NM_001294341.2; = p.X331_splice on NM_032219.4) | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV59140168; called by muse, mutect2, varscan2
- SLC6A12 | c.1537T>A p.F513I | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV62884974; called by muse, mutect2, varscan2
- SLC6A14 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 48/55 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1556694960, COSV64140784; called by muse, mutect2, varscan2
- SLC8A3 | c.1186T>A p.S396T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.429); catalogued as COSV63520879; called by muse, mutect2, varscan2
- SLCO6A1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV101134252; called by muse, mutect2, varscan2
- SLFN13 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 96/111 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53193325; called by muse, mutect2, varscan2
- SLIT3 | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV60592782; called by muse, mutect2, varscan2
- SMARCA4 | c.4030C>T p.P1344S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60793272; called by muse, mutect2, varscan2
- SMARCC2 | c.2326C>T p.R776* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as rs1296174572, COSV99911198; called by muse, mutect2, varscan2
- SMARCD2 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 61/75 reads (81%) | SIFT tolerated (0.13); PolyPhen benign (0.214); catalogued as COSV56739088; called by muse, mutect2, varscan2
- SMC1B | c.910A>T p.N304Y | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV100663157; called by muse, mutect2, varscan2
- SMC1B | c.909A>T p.E303D | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100663158; called by muse, mutect2, varscan2
- SNCAIP | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs1314042240, COSV54409038; called by muse, varscan2
- SNCAIP | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.164); catalogued as COSV54409058; called by muse, varscan2
- SNX20 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV56057536; called by muse, mutect2, varscan2
- SORL1 | c.5341A>C p.N1781H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as COSV52753881; called by muse, mutect2, varscan2
- SPAG17 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 151/165 reads (92%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV60457911; called by muse, mutect2, varscan2
- SPARCL1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.165); catalogued as COSV56803354; called by muse, mutect2, varscan2
- SPHKAP | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV60877247, COSV60887284; called by muse, mutect2, varscan2
- SPHKAP | c.1447C>T p.L483F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV60877274; called by muse, mutect2, varscan2
- ST8SIA3 | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 31/46 reads (67%) | PolyPhen probably damaging (1); catalogued as COSV60654048; called by muse, mutect2
- STAB1 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV58735566; called by muse, mutect2, varscan2
- STAB2 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV66338479; called by muse, mutect2, varscan2
- STK3 | c.774T>A p.C258* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV69223252; called by muse, mutect2, varscan2
- STPG2 | c.388-1G>A p.X130_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as COSV54796150; called by muse, mutect2, varscan2
- SUCNR1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV62912188; called by muse, mutect2, varscan2
- SUN5 | c.613G>T p.G205W | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62181012; called by muse, mutect2, varscan2
- SYCP2L | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs754946517, COSV51649573, COSV99304708; called by muse, mutect2, varscan2
- SYNE1 | c.17009C>T p.S5670F (on ENST00000367255 / NM_182961.4; = p.S5599F on NM_033071.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV54969057, COSV99555022; called by muse, mutect2, varscan2
- SYT10 | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866542712, COSV57339961; called by muse, mutect2, varscan2
- SYT10 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV57339982; called by muse, mutect2, varscan2
- SYT9 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.86); catalogued as COSV59617782; called by muse, mutect2, varscan2
- TAAR1 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV51588554; called by muse, mutect2, varscan2
- TAB1 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53370947; called by muse, mutect2, varscan2
- TAF2 | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV65417976; called by muse, mutect2, varscan2
- TAGAP | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV57851500; called by muse, mutect2, varscan2
- TAX1BP3 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1334009441, COSV50265052; called by muse, mutect2, varscan2
- TBX19 | c.1193A>G p.Q398R | Missense Mutation (SNP) | VAF 73/82 reads (89%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.063); catalogued as COSV63197385; called by muse, mutect2, varscan2
- TCEA1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV67172491; called by muse, mutect2, varscan2
- TENM3 | c.4108G>A p.E1370K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV69306561; called by muse, mutect2, varscan2
- TENM3 | c.5515G>A p.E1839K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs201172018, COSV101305325; called by muse, mutect2, varscan2
- TICRR | c.2617C>G p.L873V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs375069166, COSV99176307; called by muse, mutect2, varscan2
- TIGD3 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 52/229 reads (23%) | catalogued as COSV52889120; called by muse, mutect2, varscan2
- TLL1 | c.1159-2A>G p.X387_splice | Splice Site (SNP) | VAF 12/24 reads (50%) | catalogued as COSV50276294; called by muse, mutect2, varscan2
- TLR2 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52606095; called by muse, mutect2, varscan2
- TM4SF1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.251); catalogued as rs549456709, COSV59524840; called by muse, mutect2, varscan2
- TM7SF2 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1332211373, COSV54207081; called by muse, mutect2, varscan2
- TMC2 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV62652318; called by muse, mutect2, varscan2
- TMEM200A | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.72); PolyPhen benign (0.092); catalogued as COSV51650951; called by muse, mutect2, varscan2
- TMEM68 | c.333A>T p.E111D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV58170755; called by muse, mutect2, varscan2
- TMIGD3 | c.334C>T p.R112C (on ENST00000369717 / NM_001081976.2; = p.R193C on NM_020683.7) | Missense Mutation (SNP) | VAF 70/72 reads (97%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs368261284; called by muse, mutect2, varscan2
- TMPPE | c.179C>A p.S60Y | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56563419; called by muse, mutect2, varscan2
- TMTC4 | c.52C>G p.P18A (on ENST00000376234 / NM_001350577.2; = p.P37A on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60891448, COSV60892050; called by muse, mutect2, varscan2
- TNFRSF10D | c.700A>C p.K234Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.866); catalogued as COSV100441735, COSV57035605; called by muse, mutect2, varscan2
- TOP3B | c.1187C>G p.A396G | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV64117190; called by muse, mutect2
- TP53 | c.981T>A p.Y327* | Nonsense Mutation (SNP) | VAF 50/55 reads (91%) | catalogued as COSV52678878, COSV52914365, COSV52993701; called by muse, mutect2, varscan2
- TPD52L1 | c.489G>A p.T163= | Splice Region (SNP) | VAF 6/51 reads (12%) | catalogued as rs267600791, COSV59191475; called by muse, mutect2, varscan2
- TPH2 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV61591813; called by muse, mutect2, varscan2
- TRANK1 | c.7012G>A p.G2338R | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV57148820; called by muse, mutect2, varscan2
- TRANK1 | c.6595C>T p.P2199S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs757838277, COSV57148843; called by muse, mutect2, varscan2
- TRAT1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55467290; called by muse, mutect2, varscan2
- TRBV27 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs184104605; called by muse, mutect2, varscan2
- TRIML1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV60194171; called by muse, mutect2, varscan2
- TRPC7 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61457388; called by muse, mutect2, varscan2
- TRPM6 | c.2437A>G p.N813D | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV62509032; called by muse, mutect2, varscan2
- TTN | c.87481G>A p.G29161R (on ENST00000591111; = p.G21737R on NM_003319.4) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | PolyPhen probably damaging (1); catalogued as COSV60024078; called by muse, mutect2, varscan2
- TTN | c.79484G>A p.G26495E (on ENST00000591111; = p.G19071E on NM_003319.4) | Missense Mutation (SNP) | VAF 14/29 reads (48%) | PolyPhen possibly damaging (0.88); catalogued as COSV60024116; called by muse, mutect2, varscan2
- TTN | c.37414G>A p.D12472N (on ENST00000591111; = p.D5048N on NM_003319.4) | Missense Mutation (SNP) | VAF 19/35 reads (54%) | PolyPhen benign (0.001); catalogued as COSV60024188; called by muse, mutect2, varscan2
- TTN | c.31003C>T p.P10335S (on ENST00000591111; = p.P9408S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | PolyPhen probably damaging (0.998); catalogued as COSV60024222; called by muse, varscan2
- TTN | c.30988C>G p.P10330A (on ENST00000591111; = p.P9403A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | PolyPhen benign (0.015); catalogued as COSV60024233; called by muse, varscan2
- TTN | c.12983C>T p.P4328L (on ENST00000591111; = p.P4282L on NM_003319.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100607598; called by muse, mutect2, varscan2
- TTN | c.11437G>A p.E3813K (on ENST00000591111; = p.E3767K on NM_003319.4) | Missense Mutation (SNP) | VAF 38/87 reads (44%) | catalogued as COSV59894244; called by muse, mutect2, varscan2
- UBA7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV61092132; called by muse, mutect2, varscan2
- UCP2 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60104682; called by muse, mutect2, varscan2
- UGT2A3 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs537304565, COSV52359835; called by muse, mutect2, varscan2
- UPB1 | c.374T>A p.F125Y | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.894); catalogued as COSV58113347; called by muse, mutect2, varscan2
- USH2A | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 121/127 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767209934, CM1410059, COSV56358108, COSV56377053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP33 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV100657039, COSV62469234; called by muse, mutect2, varscan2
- VCAN | c.2141G>A p.G714E | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as COSV54104070; called by muse, mutect2, varscan2
- VEPH1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 69/121 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV100747504; called by muse, mutect2, varscan2
- VGLL4 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs1461609402, COSV56076742; called by muse, mutect2, varscan2
- VIL1 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs769529653, COSV50287459; called by muse, mutect2, varscan2
- VPS39 | c.2227C>T p.R743W (on ENST00000348544 / NM_001301138.2; = p.R732W on NM_015289.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs199874571, COSV58789425; called by muse, mutect2, varscan2
- VWA3B | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV68242574; called by muse, mutect2, varscan2
- VWCE | c.2276G>A p.G759E | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV57111569; called by muse, varscan2
- VWF | c.2990G>A p.G997E | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54618872; called by muse, mutect2, varscan2
- WDR19 | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as COSV56464838; called by muse, mutect2, varscan2
- WRN | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs776831463, COSV53299551; called by muse, mutect2, varscan2
- WWC3 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs1183508035, COSV66503024; called by muse, mutect2, varscan2
- XIRP1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 125/192 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as rs1235695139, COSV61138219; called by muse, mutect2, varscan2
- XIRP2 | c.538G>A p.E180K (on ENST00000628543; = p.E355K on NM_152381.6) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV54733354; called by muse, mutect2
- XKR9 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1000729653, COSV68772873; called by muse, mutect2, varscan2
- XKRX | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 45/50 reads (90%) | catalogued as COSV100139644; called by muse, mutect2, varscan2
- XKRX | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 54/60 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV60707892; called by muse, mutect2, varscan2
- XPO1 | c.1844T>C p.L615S | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68945823; called by muse, mutect2, varscan2
- ZAN | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 72/146 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV61808512; called by muse, mutect2, varscan2
- ZBTB34 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 29/30 reads (97%) | catalogued as COSV100043680, COSV59859802; called by muse, mutect2, varscan2
- ZCWPW1 | c.800G>A p.W267* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV61248861; called by muse, mutect2, varscan2
- ZFHX4 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as COSV50734255; called by muse, mutect2
- ZMAT4 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368933570; called by muse, mutect2, varscan2
- ZNF10 | c.1325T>A p.F442Y | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV50212187; called by muse, mutect2, varscan2
- ZNF106 | c.2110C>T p.Q704* | Nonsense Mutation (SNP) | VAF 50/129 reads (39%) | catalogued as COSV55516286; called by muse, mutect2, varscan2
- ZNF197 | c.1724T>A p.F575Y | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60360446; called by muse, mutect2, varscan2
- ZNF235 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.69); catalogued as COSV52155496; called by muse, mutect2, varscan2
- ZNF41 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 36/37 reads (97%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57441676, COSV57442407; called by muse, mutect2, varscan2
- ZNF493 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs774511978, COSV62749937; called by muse, mutect2, varscan2
- ZNF558 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.942); catalogued as COSV56863059; called by muse, mutect2, varscan2
- ZNF585A | c.1982C>T p.P661L (on ENST00000292841 / NM_001288800.2; = p.P606L on NM_152655.3) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99493011; called by muse, mutect2, varscan2
- ZNF607 | c.1879C>T p.H627Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62205955; called by muse, mutect2, varscan2
- ZNF668 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV56213912; called by muse, mutect2, varscan2
- ZNF7 | c.1348T>A p.F450I | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57383506; called by muse, mutect2, varscan2
- ZZEF1 | c.3805C>T p.P1269S | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV67557257; called by muse, mutect2, varscan2
- CYP8B1 | c.864del p.P289Lfs*11 | Frame Shift Del (DEL) | VAF 10/13 reads (77%) | called by mutect2, varscan2
- DDX3X | c.199del p.A67Rfs*153 (on ENST00000399959; = p.A68Rfs*153 on NM_001356.5) | Frame Shift Del (DEL) | VAF 28/43 reads (65%) | called by mutect2, pindel, varscan2
- DDX60L | c.3283C>T p.P1095S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by mutect2, varscan2
- FCGBP | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPLN | c.366del p.K123Rfs*81 (on ENST00000554301; = p.K123Rfs*76 on NM_173462.4) | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- TRAV18 | c.119T>G p.L40* | Nonsense Mutation (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ABCA3 | c.309C>T p.I103= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV57052947; called by muse, mutect2, varscan2
- ABCC11 | c.2007G>A p.G669= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV62322846; called by muse, mutect2, varscan2
- ABCG4 | c.1263C>T p.F421= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as COSV56643425; called by muse, mutect2, varscan2
- ACAN | c.2436C>T p.F812= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100717798; called by muse, mutect2
- ACE | c.3180C>T p.I1060= | Silent (SNP) | VAF 38/46 reads (83%) | catalogued as rs754344947, COSV52003209; called by muse, mutect2, varscan2
- ACSM1 | c.996C>T p.I332= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV54635320; called by muse, mutect2, varscan2
- ACSS1 | c.1077T>A p.L359= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV60219875; called by muse, mutect2, varscan2
- ADAM29 | c.165C>T p.I55= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100821864, COSV63663246; called by muse, mutect2, varscan2
- ADAMTS3 | c.3216C>T p.V1072= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as COSV54390413; called by muse, mutect2, varscan2
- ADAMTS7 | c.861C>T p.I287= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV66307042; called by muse, varscan2
- ADCY3 | c.1350C>T p.I450= | Silent (SNP) | VAF 68/138 reads (49%) | catalogued as COSV53167172; called by muse, mutect2, varscan2
- ADCY8 | c.685C>T p.L229= | Silent (SNP) | VAF 53/76 reads (70%) | catalogued as COSV53905995; called by muse, mutect2, varscan2
- ADGRB3 | c.2868C>T p.F956= | Silent (SNP) | VAF 31/47 reads (66%) | catalogued as COSV53242986; called by muse, mutect2, varscan2
- ADGRL1 | c.1182G>A p.L394= (on ENST00000340736 / NM_001008701.3; = p.L389= on NM_014921.5) | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV61564513; called by muse, mutect2, varscan2
- ADGRL4 | c.33C>T p.S11= | Silent (SNP) | VAF 29/33 reads (88%) | catalogued as rs1480498804, COSV66061384, COSV66062028; called by muse, mutect2, varscan2
- AGR2 | c.33C>A p.L11= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV68596491; called by muse, mutect2, varscan2
- AHNAK2 | c.10710C>T p.D3570= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as rs766158374, COSV100317080; called by muse, mutect2, varscan2
- AJM1 | c.2233C>T p.L745= | Silent (SNP) | VAF 26/26 reads (100%) | catalogued as rs1454054794, COSV56032804, COSV99915345; called by muse, mutect2, varscan2
- AKAP4 | c.1317G>A p.K439= | Silent (SNP) | VAF 57/60 reads (95%) | catalogued as COSV62074335; called by muse, mutect2, varscan2
- ALMS1 | c.7761C>T p.F2587= | Silent (SNP) | VAF 64/155 reads (41%) | catalogued as rs1553409598, COSV52508868; ClinVar: likely benign; called by muse, mutect2, varscan2
- AOC1 | c.1713G>A p.R571= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs1400235736, COSV62868393; called by muse, mutect2, varscan2
- ARMC9 | c.1947C>T p.P649= | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as COSV63020725; called by muse, mutect2, varscan2
- ATP2A2 | c.2598C>T p.F866= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57875347; called by muse, mutect2, varscan2
- ATP8B4 | c.2916C>T p.I972= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV52714516; called by muse, mutect2, varscan2
- ATP9A | c.2479T>C p.L827= | Silent (SNP) | VAF 159/347 reads (46%) | catalogued as COSV58765991; called by muse, mutect2, varscan2
- ATP9A | c.171C>T p.V57= | Silent (SNP) | VAF 78/164 reads (48%) | catalogued as COSV58766000; called by muse, mutect2, varscan2
- B3GNT3 | c.534C>T p.F178= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV59437699; called by muse, mutect2, varscan2
- B4GALNT3 | c.2235C>T p.V745= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs139340276; called by muse, mutect2, varscan2
- BCAS1 | c.1617G>A p.G539= | Silent (SNP) | VAF 61/120 reads (51%) | catalogued as COSV65085650; called by muse, mutect2, varscan2
- BCO2 | c.750G>A p.K250= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV63063234; called by muse, mutect2, varscan2
- BEND4 | c.1539G>A p.G513= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1360708257, COSV72469074; called by muse, mutect2, varscan2
- BICRAL | c.444C>T p.S148= | Silent (SNP) | VAF 72/163 reads (44%) | catalogued as COSV100017938, COSV58405171; called by muse, mutect2, varscan2
- BMP5 | c.879A>G p.G293= | Silent (SNP) | VAF 43/111 reads (39%) | catalogued as COSV63703005; called by muse, mutect2, varscan2
- BNC1 | c.261C>T p.S87= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV61757305; called by muse, mutect2, varscan2
- BPIFB2 | c.1056C>T p.F352= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV50064347; called by muse, mutect2, varscan2
- BTC | c.240G>A p.G80= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV67547565; called by muse, mutect2, varscan2
- C1orf94 | c.1029G>A p.K343= (on ENST00000488417 / NM_001134734.2; = p.K153= on NM_032884.5) | Silent (SNP) | VAF 104/111 reads (94%) | catalogued as rs888999871, COSV64913881; called by muse, mutect2, varscan2
- C6 | c.1203G>A p.R401= | Silent (SNP) | VAF 44/78 reads (56%) | catalogued as COSV54709548; called by muse, mutect2, varscan2
- C6orf118 | c.1227G>A p.L409= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as rs1223826144, COSV100024832, COSV57814630; called by muse, mutect2, varscan2
- CACNA1H | c.2286G>A p.R762= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV61989332; called by muse, mutect2, varscan2
- CACNA1H | c.2559C>T p.I853= | Silent (SNP) | VAF 64/126 reads (51%) | catalogued as COSV61989341; called by muse, mutect2, varscan2
- CACNG3 | c.750C>T p.I250= | Silent (SNP) | VAF 52/87 reads (60%) | catalogued as rs148951012; called by muse, mutect2, varscan2
- CAPN5 | c.1743C>T p.I581= (on ENST00000456580; = p.I541= on NM_004055.5) | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV53687527; called by muse, mutect2, varscan2
- CCDC157 | c.186T>G p.V62= | Silent (SNP) | VAF 56/223 reads (25%) | catalogued as COSV100600244; called by muse, mutect2
- CCDC158 | c.3075A>G p.L1025= | Silent (SNP) | VAF 93/168 reads (55%) | catalogued as rs780247919, COSV66355793; called by muse, mutect2, varscan2
- CCDC88C | c.2376G>A p.L792= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV66237628; called by muse, mutect2, varscan2
- CD101 | c.1095C>T p.F365= | Silent (SNP) | VAF 79/83 reads (95%) | catalogued as COSV56717749; called by muse, mutect2, varscan2
- CD248 | c.1389C>T p.A463= | Silent (SNP) | VAF 61/94 reads (65%) | catalogued as COSV60936378; called by muse, mutect2, varscan2
- CDHR3 | c.1983G>A p.R661= | Silent (SNP) | VAF 85/170 reads (50%) | catalogued as rs1401738685, COSV100488191, COSV58416593; called by muse, mutect2, varscan2
- CELSR1 | c.5283C>T p.S1761= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs141170525; called by muse, mutect2, varscan2
- CEP68 | c.603C>T p.S201= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs746018404, COSV53124758; called by muse, mutect2
- CETN1 | c.144C>T p.I48= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as COSV59121282; called by muse, mutect2, varscan2
- CLEC17A | c.570G>A p.V190= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV60427604; called by muse, mutect2, varscan2
- CLEC1A | c.717C>T p.I239= | Silent (SNP) | VAF 71/117 reads (61%) | catalogued as rs1297028522, COSV59531868; called by muse, mutect2, varscan2
- CLPSL1 | c.228C>T p.F76= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as rs373782315; called by muse, mutect2, varscan2
- COL12A1 | c.5544G>A p.R1848= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV59395110; called by muse, mutect2, varscan2
- COL13A1 | c.1575G>A p.V525= (on ENST00000398978 / NM_001130103.2; = p.V468= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV62569478; called by muse, mutect2, varscan2
- COL20A1 | c.783C>T p.A261= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV58916305; called by muse, mutect2, varscan2
- CPAMD8 | c.4146C>T p.L1382= (on ENST00000651564; = p.L1335= on NM_015692.5) | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV71596505; called by muse, mutect2
- CPXM1 | c.1662G>A p.Q554= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as COSV66045288; called by muse, mutect2, varscan2
- CREB5 | c.1272G>A p.L424= (on ENST00000357727 / NM_182898.4; = p.L417= on NM_004904.3) | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as COSV63220367; called by muse, mutect2, varscan2
- CXCL9 | c.306G>A p.G102= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1212889448, COSV53578578; called by muse, mutect2, varscan2
- CYP19A1 | c.681C>T p.L227= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs763732916, COSV53059053; called by muse, mutect2, varscan2
- CYP2C18 | c.549C>T p.F183= | Silent (SNP) | VAF 50/62 reads (81%) | catalogued as COSV53672007; called by muse, mutect2, varscan2
- CYP3A43 | c.813C>T p.F271= | Silent (SNP) | VAF 56/109 reads (51%) | catalogued as rs908333742, COSV55935947; called by muse, mutect2, varscan2
- DCAF11 | c.561C>T p.F187= | Silent (SNP) | VAF 54/93 reads (58%) | catalogued as COSV58109042; called by muse, mutect2, varscan2
- DCAF12L1 | c.1146C>T p.F382= | Silent (SNP) | VAF 34/36 reads (94%) | catalogued as COSV64421716; called by muse, mutect2, varscan2
- DIAPH1 | c.2656C>T p.L886= | Silent (SNP) | VAF 102/126 reads (81%) | catalogued as COSV53881895; called by muse, mutect2, varscan2
- DMWD | c.1569C>T p.F523= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs374890935; called by muse, mutect2, varscan2
- DNAH17 | c.11346G>A p.E3782= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as rs1193167208, COSV67753538; called by muse, mutect2, varscan2
- DNAH3 | c.10732T>C p.L3578= | Silent (SNP) | VAF 64/145 reads (44%) | catalogued as COSV54519195; called by muse, mutect2, varscan2
- DNAH5 | c.12553C>T p.L4185= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV54221738, COSV99455403; called by muse, mutect2, varscan2
- DNAL4 | c.289C>T p.L97= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV53308827; called by muse, mutect2
- DOCK7 | c.1056A>G p.Q352= | Silent (SNP) | VAF 221/233 reads (95%) | catalogued as rs948445533, COSV52003959; called by muse, mutect2, varscan2
- DPP7 | c.1213A>C p.R405= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV65371267; called by muse, mutect2, varscan2
- DUOXA1 | c.27C>T p.P9= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV50993435; called by muse, varscan2
- EPB41L3 | c.738G>T p.G246= | Silent (SNP) | VAF 145/197 reads (74%) | catalogued as COSV59451852; called by muse, mutect2, varscan2
- EPHA10 | c.306C>T p.F102= | Silent (SNP) | VAF 155/166 reads (93%) | catalogued as rs138523815; called by muse, mutect2, varscan2
- EPHB2 | c.909T>C p.C303= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs1256565919, COSV65862284; ClinVar: likely benign; called by muse, mutect2
- ESYT3 | c.642G>A p.G214= | Silent (SNP) | VAF 77/108 reads (71%) | catalogued as rs987728046, COSV56680299; called by muse, mutect2, varscan2
- ETS1 | c.1206C>T p.I402= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1487598019, COSV60093249; called by muse, mutect2, varscan2
- EXOC3 | c.1917C>T p.F639= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1389535913, COSV59266567; called by muse, mutect2, varscan2
- FAT2 | c.558C>T p.A186= | Silent (SNP) | VAF 42/290 reads (14%) | catalogued as COSV55818837; called by muse, mutect2, varscan2
- FBLN7 | c.1200G>A p.Q400= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs565012617, COSV55616075; called by muse, mutect2, varscan2
- FCGBP | c.2193G>A p.S731= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs756784565; called by muse, mutect2, varscan2
- FGF23 | c.531C>T p.H177= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs759288956, COSV52975956; called by muse, varscan2
- FGF7 | c.183A>G p.G61= | Silent (SNP) | VAF 54/123 reads (44%) | catalogued as COSV51066019; called by muse, mutect2, varscan2
- FHOD1 | c.2088C>T p.D696= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV99264044; called by muse, mutect2, varscan2
- FNDC1 | c.1299C>T p.F433= | Silent (SNP) | VAF 108/175 reads (62%) | catalogued as COSV51930815; called by muse, mutect2, varscan2
- FSTL5 | c.1242C>T p.I414= | Silent (SNP) | VAF 75/129 reads (58%) | catalogued as rs777513850, COSV60186418; called by muse, mutect2, varscan2
- GABRA6 | c.408C>T p.F136= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as COSV50880397; called by muse, mutect2, varscan2
- GALNT14 | c.690C>T p.I230= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV61104762; called by muse, mutect2, varscan2
- GBP6 | c.1881A>G p.K627= | Silent (SNP) | VAF 73/79 reads (92%) | catalogued as COSV65010674, COSV65011378; called by muse, mutect2, varscan2
- GCC2 | c.3399G>A p.K1133= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs756776491, COSV59174678; called by muse, mutect2, varscan2
- GJC1 | c.75C>T p.L25= | Silent (SNP) | VAF 25/31 reads (81%) | catalogued as COSV57911169; called by muse, mutect2, varscan2
- GMPPA | c.198C>T p.T66= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as COSV58006835; called by muse, mutect2, varscan2
- GPR32 | c.801C>T p.I267= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV54513998; called by muse, mutect2, varscan2
- GRIN2A | c.2772C>T p.F924= | Silent (SNP) | VAF 74/225 reads (33%) | catalogued as COSV58030931; called by muse, mutect2, varscan2
- GSTM2 | c.582C>T p.I194= | Silent (SNP) | VAF 158/168 reads (94%) | catalogued as COSV53982446; called by muse, mutect2, varscan2
- GTPBP6 | c.1315C>T p.L439= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100397830, COSV58204913; called by muse, mutect2, varscan2
- HCLS1 | c.720G>A p.A240= | Silent (SNP) | VAF 42/55 reads (76%) | catalogued as rs750027205, COSV57521740; called by muse, mutect2, varscan2
- HIP1 | c.681G>A p.Q227= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs1554497124, COSV100417395; called by muse, mutect2, varscan2
- HIVEP1 | c.1119C>T p.I373= | Silent (SNP) | VAF 59/186 reads (32%) | catalogued as COSV65100907; called by muse, mutect2, varscan2
- HRG | c.633C>T p.H211= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV51645312; called by muse, mutect2
- HRNR | c.6225A>C p.S2075= | Silent (SNP) | VAF 244/318 reads (77%) | catalogued as rs761949809, COSV64257302; called by muse, mutect2, varscan2
- HTR1A | c.1138C>T p.L380= | Silent (SNP) | VAF 181/260 reads (70%) | catalogued as rs1358041094, COSV60500625, COSV60500752; called by muse, mutect2, varscan2
- HYDIN | c.14067C>T p.I4689= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs567198761, COSV66642465; called by mutect2, varscan2
- IARS1 | c.3264T>C p.C1088= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as COSV65113030; called by mutect2, varscan2
- IGHD | c.573C>T p.F191= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs772392001, COSV101162854; called by muse, mutect2, varscan2
- IL1RN | c.435C>T p.F145= (on ENST00000409930 / NM_173842.3; = p.F127= on NM_000577.5) | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV52080562; called by muse, mutect2, varscan2
- INAVA | c.957C>T p.V319= | Silent (SNP) | VAF 130/139 reads (94%) | catalogued as rs1365466678, COSV66256462; called by muse, mutect2, varscan2
- KIAA0319 | c.1929C>T p.T643= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs138076041; called by muse, mutect2, varscan2
- KLHDC10 | c.1053C>T p.F351= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as rs781159618, COSV59051530; called by muse, mutect2, varscan2
- KLHL32 | c.1860C>T p.I620= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV51520311, COSV51520381; called by muse, mutect2
- KRT76 | c.480A>G p.V160= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV100196508, COSV60120064; called by muse, mutect2, varscan2
- KRTAP9-4 | c.408G>A p.E136= | Silent (SNP) | VAF 112/202 reads (55%) | catalogued as COSV61897967; called by muse, varscan2
- LAIR1 | c.822C>T p.P274= | Silent (SNP) | VAF 62/127 reads (49%) | catalogued as COSV57307304; called by muse, mutect2, varscan2
- LAMA3 | c.750G>A p.R250= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs1039069694, COSV58067826; called by muse, mutect2, varscan2
- LAMB3 | c.2754C>A p.A918= | Silent (SNP) | VAF 65/74 reads (88%) | catalogued as COSV50521485; called by muse, mutect2, varscan2
- LARP7 | c.279A>T p.A93= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as COSV60520813; called by muse, mutect2, varscan2
- LCA5 | c.783G>A p.R261= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV63970980, COSV63971236; called by muse, mutect2
- LILRB1 | c.1413C>T p.S471= (on ENST00000427581; = p.S435= on NM_006669.6) | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV61117708; called by muse, mutect2, varscan2
- LILRB2 | c.945C>T p.I315= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV58744980; called by muse, mutect2, varscan2
- LIMCH1 | c.870G>A p.E290= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV58282366; called by muse, mutect2, varscan2
- LRP2 | c.9792C>T p.I3264= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as COSV55551498; called by muse, mutect2, varscan2
- MALT1 | c.327C>T p.F109= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV61934759; called by muse, mutect2, varscan2
- MAN2A2 | c.282C>T p.V94= | Silent (SNP) | VAF 59/103 reads (57%) | catalogued as COSV64638128; called by muse, mutect2, varscan2
- MAP4K2 | c.1447C>T p.L483= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV53642859; called by muse, mutect2, varscan2
- MAPK15 | c.228C>T p.L76= | Silent (SNP) | VAF 58/152 reads (38%) | catalogued as rs868962914, COSV62028159; called by muse, mutect2, varscan2
- MEGF10 | c.3018C>T p.S1006= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as COSV57248588; called by muse, mutect2, varscan2
- MESD | c.663C>T p.S221= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV55725049; called by muse, mutect2, varscan2
- MOBP | c.120G>A p.V40= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV60654301; called by muse, mutect2, varscan2
- MROH2B | c.297C>T p.F99= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV68183532; called by muse, mutect2, varscan2
- MTMR14 | c.858C>T p.F286= | Silent (SNP) | VAF 61/88 reads (69%) | catalogued as COSV56004635; called by muse, mutect2, varscan2
- MUC13 | c.1155G>A p.G385= | Silent (SNP) | VAF 40/65 reads (62%) | catalogued as COSV60699285; called by muse, mutect2, varscan2
- MUC2 | c.1587G>A p.G529= | Silent (SNP) | VAF 14/18 reads (78%) | called by muse, mutect2, varscan2
- MYH6 | c.525C>T p.L175= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV62450022; called by muse, mutect2, varscan2
- MYLK | c.1425G>A p.L475= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV60609536; called by muse, mutect2
- MYO5A | c.2250C>T p.F750= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV62559727; called by muse, mutect2, varscan2
- MYO5B | c.3115C>T p.L1039= | Silent (SNP) | VAF 26/273 reads (10%) | catalogued as COSV53217785; called by muse, mutect2
- MYOCD | c.2022C>T p.V674= | Silent (SNP) | VAF 35/42 reads (83%) | catalogued as COSV58502988; called by muse, mutect2, varscan2
- MYOM1 | c.4590C>T p.V1530= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV55290842; called by muse, mutect2, varscan2
- NCAPD2 | c.3720C>T p.L1240= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV57520997; called by muse, mutect2, varscan2
- NDNF | c.1686G>A p.V562= | Silent (SNP) | VAF 62/116 reads (53%) | catalogued as COSV65633287; called by muse, mutect2, varscan2
- NDNF | c.537C>T p.D179= | Silent (SNP) | VAF 49/136 reads (36%) | catalogued as COSV65633290; called by muse, mutect2, varscan2
- NDRG3 | c.126C>T p.V42= (on ENST00000349004 / NM_032013.4; = p.V30= on NM_022477.4) | Silent (SNP) | VAF 59/145 reads (41%) | catalogued as COSV62421820; called by muse, mutect2, varscan2
- NDRG4 | c.78C>T p.P26= (on ENST00000570248 / NM_001378344.1; = p.P58= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99262009; called by muse, mutect2, varscan2
- NDUFA6 | c.147A>G p.Q49= | Silent (SNP) | VAF 42/130 reads (32%) | catalogued as COSV58938566; called by muse, mutect2, varscan2
- NETO1 | c.1485C>T p.I495= | Silent (SNP) | VAF 36/46 reads (78%) | catalogued as rs201303366, COSV100198322, COSV55003064; called by muse, mutect2, varscan2
- NEXMIF | c.2940G>A p.Q980= | Silent (SNP) | VAF 23/29 reads (79%) | catalogued as COSV50029340, COSV99282199; called by muse, mutect2, varscan2
- NLRP14 | c.534C>T p.I178= | Silent (SNP) | VAF 62/98 reads (63%) | catalogued as rs138061199, COSV55064824; called by muse, mutect2, varscan2
- NPHS1 | c.261G>A p.G87= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV62287631; called by muse, mutect2, varscan2
- NSD1 | c.1191C>T p.V397= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as COSV61775625; called by muse, mutect2, varscan2
- NXPH4 | c.420C>T p.F140= | Silent (SNP) | VAF 35/69 reads (51%) | catalogued as COSV61073859; called by muse, mutect2, varscan2
- NYAP2 | c.702C>T p.P234= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as rs775269602, COSV56004066; called by muse, mutect2, varscan2
- OLFM1 | c.876C>T p.H292= (on ENST00000371793 / NM_001282611.2; = p.H274= on NM_014279.5) | Silent (SNP) | VAF 79/90 reads (88%) | catalogued as rs772313066, COSV53278109; called by muse, mutect2, varscan2
- OPN4 | c.411C>T p.L137= | Silent (SNP) | VAF 25/30 reads (83%) | catalogued as COSV54116116; called by muse, mutect2, varscan2
- OR10AG1 | c.465C>T p.F155= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV56631984; called by muse, mutect2, varscan2
- OR10S1 | c.681C>T p.L227= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as COSV73342751; called by muse, mutect2, varscan2
- OR11H1 | c.897G>A p.K299= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs1231237467; called by mutect2, varscan2
- OR1F1 | c.309C>T p.F103= | Silent (SNP) | VAF 84/220 reads (38%) | catalogued as rs267604532, COSV58960923; called by muse, mutect2, varscan2
- OR4A15 | c.924G>A p.G308= | Silent (SNP) | VAF 51/83 reads (61%) | catalogued as COSV59035028; called by muse, mutect2, varscan2
- OR4D11 | c.702G>A p.R234= | Silent (SNP) | VAF 113/166 reads (68%) | catalogued as rs865930437, COSV57585482; called by muse, mutect2, varscan2
- OR52K2 | c.828C>T p.I276= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as rs780621028, COSV57834535; called by muse, mutect2, varscan2
- OR5AK2 | c.621G>A p.L207= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV58803808; called by muse, mutect2
- OR5AU1 | c.174C>T p.P58= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV58615535; called by muse, mutect2, varscan2
- OR5B17 | c.795C>T p.S265= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as COSV62160252; called by muse, mutect2, varscan2
- OR6V1 | c.733C>T p.L245= | Silent (SNP) | VAF 55/145 reads (38%) | catalogued as COSV69236908, COSV69237197; called by muse, mutect2, varscan2
- OR8D2 | c.309C>T p.F103= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV62488297; called by muse, mutect2, varscan2
- OR8I2 | c.339C>T p.F113= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV56167742; called by muse, mutect2, varscan2
- OR8K5 | c.519C>T p.V173= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as COSV57888628; called by muse, mutect2, varscan2
- OR9I1 | c.912C>T p.V304= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as rs368868026, COSV56925654, COSV56925909; called by muse, mutect2, varscan2
- OSBPL10 | c.2076G>A p.K692= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV67338832; called by muse, mutect2, varscan2
- OSBPL3 | c.1794C>T p.Y598= | Silent (SNP) | VAF 73/199 reads (37%) | catalogued as rs1319965204, COSV57652781; called by muse, mutect2, varscan2
- PCDHA12 | c.1539G>A p.E513= | Silent (SNP) | VAF 274/328 reads (84%) | catalogued as COSV56497404; called by muse, mutect2, varscan2
- PCDHAC1 | c.1932A>G p.P644= | Silent (SNP) | VAF 155/195 reads (79%) | catalogued as COSV53847754; called by muse, mutect2, varscan2
- PCNX3 | c.3828C>T p.F1276= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs1432711269, COSV63136530; called by muse, varscan2
- PDZD2 | c.1893T>G p.L631= | Silent (SNP) | VAF 68/94 reads (72%) | catalogued as COSV56857207; called by muse, mutect2, varscan2
- PER1 | c.2073C>T p.A691= | Silent (SNP) | VAF 28/30 reads (93%) | catalogued as COSV57919253; called by muse, mutect2, varscan2
- PGAP1 | c.1140C>T p.I380= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV61325851, COSV61328320; called by muse, mutect2, varscan2
- PKD1L1 | c.4641C>T p.P1547= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as rs746238686, COSV56963884; called by muse, mutect2, varscan2
- PKP3 | c.2382C>T p.F794= | Silent (SNP) | VAF 53/78 reads (68%) | catalogued as rs1462123724, COSV58986978; called by muse, mutect2, varscan2
- PLB1 | c.3654G>A p.E1218= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV59824202; called by muse, mutect2, varscan2
- PLCXD3 | c.519G>A p.A173= | Silent (SNP) | VAF 67/225 reads (30%) | catalogued as rs377065100, COSV60605164; called by muse, mutect2, varscan2
- PLEKHH1 | c.75T>C p.L25= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV61282789; called by muse, mutect2, varscan2
- PNP | c.316C>T p.L106= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV64091940; called by muse, mutect2, varscan2
- POLD1 | c.1215C>T p.Y405= | Silent (SNP) | VAF 61/142 reads (43%) | catalogued as rs1555790585, COSV101486826; ClinVar: likely benign; called by muse, mutect2, varscan2
- POU3F3 | c.1173C>T p.T391= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs199565525, COSV100796855; called by muse, varscan2
- PPL | c.1320G>A p.G440= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs200707643, COSV62046743; called by muse, varscan2
- PRAME | c.1245G>A p.G415= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV67161496; called by muse, mutect2, varscan2
- PRDM16 | c.3042C>T p.N1014= | Silent (SNP) | VAF 87/101 reads (86%) | catalogued as COSV99576305; called by muse, mutect2, varscan2
- PREX2 | c.1695G>A p.S565= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1386409533, COSV55752115; called by muse, mutect2, varscan2
- PRKCG | c.51C>T p.P17= | Silent (SNP) | VAF 70/141 reads (50%) | catalogued as COSV54727266; called by muse, mutect2, varscan2
- PRRC2C | c.4065G>A p.R1355= (on ENST00000367742; = p.R1353= on NM_015172.4) | Silent (SNP) | VAF 29/31 reads (94%) | catalogued as COSV58904794; called by muse, mutect2, varscan2
- PRSS33 | c.69G>A p.R23= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV53450793; called by muse, mutect2, varscan2
- PRSS38 | c.180C>T p.I60= | Silent (SNP) | VAF 162/175 reads (93%) | catalogued as COSV64540318; called by muse, mutect2, varscan2
- PTPRE | c.1794C>T p.I598= | Silent (SNP) | VAF 15/17 reads (88%) | catalogued as rs559961003, COSV54550309; called by muse, mutect2, varscan2
- PXDNL | c.2643C>T p.V881= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as COSV62486523; called by muse, mutect2, varscan2
- RAB11B | c.525C>T p.I175= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as rs199957705, COSV60085216; called by muse, mutect2, varscan2
- RAB27B | c.528C>T p.T176= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs267605213, COSV50494649; called by muse, mutect2
- RABEP2 | c.765C>T p.G255= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV62869329, COSV62870783; called by muse, mutect2, varscan2
- RANBP2 | c.6774C>T p.F2258= | Silent (SNP) | VAF 69/231 reads (30%) | catalogued as COSV51700267; called by muse, mutect2, varscan2
- RASGEF1C | c.228C>T p.P76= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs759700894, COSV63180330; called by muse, mutect2, varscan2
- RASGRP3 | c.21G>A p.G7= | Silent (SNP) | VAF 58/137 reads (42%) | catalogued as rs781662268, COSV67821811; called by muse, mutect2, varscan2
- RBBP8NL | c.1905G>A p.R635= | Silent (SNP) | VAF 84/225 reads (37%) | catalogued as COSV53349041; called by muse, mutect2, varscan2
- RBM7 | c.333C>T p.S111= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs373681592; called by muse, mutect2, varscan2
- RNF144A | c.492C>T p.F164= | Silent (SNP) | VAF 50/120 reads (42%) | catalogued as COSV57980895; called by muse, mutect2, varscan2
- RNF213 | c.8463C>T p.T2821= | Silent (SNP) | VAF 25/31 reads (81%) | catalogued as COSV60396116; called by muse, mutect2, varscan2
- ROBO2 | c.1791G>A p.A597= | Silent (SNP) | VAF 52/83 reads (63%) | catalogued as rs765944341, COSV59909330; called by muse, mutect2, varscan2
- RPH3A | c.519G>A p.K173= (on ENST00000389385 / NM_001143854.2; = p.K169= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV66992848; called by muse, mutect2, varscan2
- RPTN | c.2160G>A p.E720= | Silent (SNP) | VAF 295/313 reads (94%) | catalogued as COSV60167139; called by muse, mutect2, varscan2
- SEC24D | c.1464C>T p.I488= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs1400876057, COSV54879367; called by muse, mutect2, varscan2
- SEMA3D | c.1128G>A p.K376= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV52392396; called by muse, mutect2, varscan2
- SGCZ | c.582G>A p.E194= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV66013720; called by muse, mutect2, varscan2
- SIPA1L1 | c.2349C>T p.F783= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV62168385; called by muse, mutect2, varscan2
- SIRPD | c.198G>A p.K66= | Silent (SNP) | VAF 64/157 reads (41%) | catalogued as rs751636117, COSV67546547; called by muse, mutect2, varscan2
- SLC14A2 | c.1083C>T p.F361= | Silent (SNP) | VAF 35/50 reads (70%) | catalogued as COSV54908649; called by muse, mutect2, varscan2
- SLC17A2 | c.57G>A p.G19= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV55351715; called by muse, mutect2, varscan2
- SLC22A12 | c.219G>A p.L73= | Silent (SNP) | VAF 29/54 reads (54%) | catalogued as COSV60571971; called by muse, mutect2, varscan2
- SLC25A31 | c.123C>T p.I41= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV55419041; called by muse, mutect2, varscan2
- SLC5A8 | c.1338G>A p.L446= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1202278959, COSV101610586; called by muse, mutect2
- SMARCC2 | c.2325C>T p.P775= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99911199; called by muse, mutect2, varscan2
- SOAT2 | c.750T>A p.A250= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs1565627916, COSV56859365; called by muse, mutect2
- SP140 | c.1758G>A p.K586= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as rs771702086, COSV59449102; called by muse, mutect2, varscan2
- SPAG6 | c.1449G>A p.E483= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as rs892891381, COSV57619920; called by muse, mutect2, varscan2
- SPEF2 | c.3009G>A p.Q1003= | Silent (SNP) | VAF 48/148 reads (32%) | catalogued as COSV61547825; called by muse, mutect2, varscan2
- SPHKAP | c.609G>A p.T203= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs1246576109, COSV60869524; called by muse, mutect2, varscan2
- SPN | c.864C>T p.L288= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs760961418, COSV64070264; called by muse, mutect2
- SPTA1 | c.3846G>A p.K1282= | Silent (SNP) | VAF 124/130 reads (95%) | catalogued as rs773466647, COSV63752414; called by muse, mutect2, varscan2
- SULT1E1 | c.375C>T p.I125= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as COSV56946244, COSV56946933; called by muse, mutect2, varscan2
- TCF20 | c.4896C>T p.Y1632= | Silent (SNP) | VAF 105/207 reads (51%) | catalogued as rs978779347, COSV59490718; called by muse, mutect2, varscan2
- TCHH | c.5634G>A p.R1878= | Silent (SNP) | VAF 156/166 reads (94%) | catalogued as COSV64274588; called by muse, mutect2, varscan2
- TECTA | c.6459G>A p.T2153= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs764337303, COSV99879557; ClinVar: likely benign; called by mutect2, varscan2
46 further variants in this file (0 protein-altering or splice-affecting, 28 silent, 18 other) are not listed here.
